Somatic mutation profile of tumor specimen TCGA-BG-A0M2-01A (aliquot TCGA-BG-A0M2-01A-11D-A10O-09) from TCGA case TCGA-BG-A0M2, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 62.5 years (22,822 days).
Specimen TCGA-BG-A0M2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 791bea69-fd20-433f-b3e1-c07c66c5836d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0M2-10A (Blood Derived Normal), aliquot TCGA-BG-A0M2-10A-02W-A10C-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d9b82ef-4243-4ca1-ae5a-9fea5d04eed9

The open-access MAF lists 33 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, Frame Shift Del 2, Nonsense Mutation 2, 5'Flank 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 260/299 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARID5B | c.1970T>A p.F657Y | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.715); catalogued as COSV54421983; called by muse, mutect2, varscan2
- ATP9A | c.1679C>G p.T560S | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.122); catalogued as COSV58767537; called by muse, mutect2, varscan2
- C11orf24 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.722); catalogued as COSV58505774; called by muse, mutect2, varscan2
- CALCR | c.1258C>T p.R420C (on ENST00000649521 / NM_001164737.2; = p.R404C on NM_001742.4) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748757809, COSV64005404; called by muse, mutect2, varscan2
- CMYA5 | c.5692A>T p.K1898* | Nonsense Mutation (SNP) | VAF 51/57 reads (89%) | catalogued as COSV71406427; called by muse, mutect2, varscan2
- CRB1 | c.3841T>G p.L1281V | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as COSV66330990; called by muse, mutect2, varscan2
- FCAR | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.958); catalogued as rs779689519, COSV62029907; called by muse, mutect2, varscan2
- KANK1 | c.1409A>T p.Y470F | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV63212752; called by muse, mutect2, varscan2
- LGI3 | c.1340A>G p.K447R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.097); catalogued as COSV60443608; called by mutect2, varscan2
- NDUFB7 | c.193C>G p.R65G | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.185); catalogued as COSV53108438; called by muse, mutect2, varscan2
- NLRC4 | c.3038G>C p.S1013T | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV50872753; called by muse, mutect2, varscan2
- PCDHGA1 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.051); catalogued as rs11575961, COSV99062111; called by muse, mutect2, varscan2
- PPP1R7 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs144669419, COSV99298139; called by muse, mutect2, varscan2
- PROM2 | c.1702C>G p.L568V | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV58298565; called by muse, mutect2, varscan2
- RIMS1 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV53460008, COSV53467762; called by muse, mutect2, varscan2
- RNF43 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 63/72 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs886926322, COSV68457519; called by muse, mutect2, varscan2
- UHMK1 | c.1115T>G p.V372G (on ENST00000489294 / NM_175866.5; = p.G342= on NM_144624.2) | Missense Mutation (SNP) | VAF 89/359 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56420025, COSV56420285; called by muse, mutect2, varscan2
- ZNF286A | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.13); catalogued as rs761460069, COSV67845754; called by muse, mutect2, varscan2
- AKR1C8P | c.272C>G p.T91S | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- IHH | c.838del p.A280Lfs*85 | Frame Shift Del (DEL) | VAF 34/54 reads (63%) | called by mutect2, varscan2
- UBA1 | c.1626_1628dup p.I543dup | In Frame Ins (INS) | VAF 19/27 reads (70%) | called by mutect2, pindel, varscan2
- ZSCAN21 | c.824_825del p.R275Tfs*6 | Frame Shift Del (DEL) | VAF 30/100 reads (30%) | called by pindel, varscan2
- GLP2R | c.966T>A p.R322= | Silent (SNP) | VAF 57/165 reads (35%) | catalogued as COSV52325708; called by muse, mutect2, varscan2
- HCN1 | c.2049C>A p.P683= | Silent (SNP) | VAF 92/226 reads (41%) | catalogued as COSV57515442; called by muse, mutect2, varscan2
- HIVEP1 | c.2358C>T p.Y786= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV65102271; called by muse, mutect2, varscan2
- OR8H3 | c.375G>A p.A125= | Silent (SNP) | VAF 108/326 reads (33%) | catalogued as COSV57909400, COSV57909630; called by muse, mutect2, varscan2
- RHOG | c.348G>A p.K116= | Silent (SNP) | VAF 22/28 reads (79%) | catalogued as rs985346579, COSV53465574; called by muse, mutect2, varscan2
- SCNN1B | c.642A>G p.A214= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV56305440; called by muse, mutect2, varscan2
- ZBTB7C | c.195C>T p.A65= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs529891239, COSV59689130; called by muse, mutect2
- ZFP91 | c.1140C>G p.A380= | Silent (SNP) | VAF 41/141 reads (29%) | catalogued as COSV60159372; called by muse, mutect2, varscan2
- CUX1 | chr7:101816058 C>G | 5'Flank (SNP) | VAF 12/39 reads (31%) | catalogued as COSV52902307, COSV99472199; called by muse, mutect2, varscan2
- MIR525 | n.51A>G | RNA (SNP) | VAF 105/272 reads (39%) | called by muse, mutect2, varscan2
